Somatic mutation profile of tumor specimen 62f5840e-6cd7-4200-b651-645e53 (aliquot 62f5840e-6cd7-4200-b651-645e53_D6_1) from CPTAC case 01OV045, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 62f5840e-6cd7-4200-b651-645e53: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c773a54-0209-4fac-a2a9-983f983296db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1d5572aa-ce3a-4928-8d93-86774f (Blood Derived Normal), aliquot 1d5572aa-ce3a-4928-8d93-86774f_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38d0e25c-fb27-45c0-8111-95007b67cbb9

The open-access MAF lists 162 somatic variants for this specimen: 121 protein-altering or splice-affecting, 28 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 28, Frame Shift Del 9, Intron 6, Nonsense Mutation 4, Splice Region 3, Splice Site 3, RNA 3, 3'Flank 2, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 86/421 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55777867; called by muse, mutect2, varscan2
- ARHGEF10 | c.827C>T p.S276L (on ENST00000398564; = p.S251L on NM_014629.4) | Missense Mutation (SNP) | VAF 105/541 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144004435; called by muse, mutect2, varscan2
- ATXN7L1 | c.1922del p.S641Ifs*40 | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | catalogued as COSV66300656; called by pindel, varscan2
- BRAF | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.083); catalogued as rs397507455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCSER2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs750250954, COSV56504046; called by muse, mutect2, varscan2
- CD2AP | c.1552dup p.I518Nfs*17 | Frame Shift Ins (INS) | VAF 11/69 reads (16%) | catalogued as rs745360728; called by mutect2, pindel, varscan2
- CEP89 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768932479, COSV59864189; called by muse, mutect2, varscan2
- COL9A2 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 162/832 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs774793213; called by muse, mutect2, varscan2
- CUX1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 171/669 reads (26%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); catalogued as rs868942566; called by muse, mutect2, varscan2
- DLG5 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs759880264; called by muse, mutect2, varscan2
- ELAVL2 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 82/274 reads (30%) | catalogued as rs867496241, COSV99805296; called by muse, mutect2, varscan2
- EML6 | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs373462956; called by muse, mutect2, varscan2
- GRIP2 | c.1522C>G p.R508G (on ENST00000619221; = p.R411G on NM_001080423.4) | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as rs190866851; called by muse, mutect2, varscan2
- HNRNPR | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV56419981; called by muse, mutect2, varscan2
- INPPL1 | c.1867A>G p.I623V | Missense Mutation (SNP) | VAF 143/721 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.033); catalogued as rs200686213, COSV53359169; called by muse, mutect2, varscan2
- IQCE | c.1901C>T p.T634I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV58077691; called by muse, mutect2, varscan2
- KIF16B | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs746435934; called by muse, mutect2, varscan2
- KIF20B | c.4485T>A p.F1495L (on ENST00000371728 / NM_001284259.2; = p.F1455L on NM_016195.4) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1304082399, COSV53302564; called by muse, mutect2, varscan2
- LGSN | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146253789; called by muse, mutect2, varscan2
- LHB | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 128/470 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.903); catalogued as rs760249612; called by muse, mutect2
- LRRIQ1 | c.1864A>G p.K622E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs899062257; called by muse, mutect2, varscan2
- MSH2 | c.174C>G p.F58L | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372189599, COSV51880148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTMR11 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1482750992; called by muse, mutect2, varscan2
- MUC12 | c.692C>G p.P231R (on ENST00000379442; = p.P88R on NM_001164462.1) | Missense Mutation (SNP) | VAF 81/357 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.811); catalogued as rs1390578193; called by muse, mutect2, varscan2
- MYBPC2 | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.402); catalogued as rs1399729991; called by muse, mutect2, varscan2
- NIBAN1 | c.2068C>T p.L690F | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as rs1483439813; called by muse, mutect2, varscan2
- OBSCN | c.23086C>T p.R7696W | Missense Mutation (SNP) | VAF 99/484 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs541725106, COSV63001241; called by muse, mutect2, varscan2
- OR2T12 | c.879T>G p.S293R | Missense Mutation (SNP) | VAF 99/550 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1394643771; called by muse, mutect2, varscan2
- OR5AU1 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 169/580 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV58615928; called by muse, mutect2, varscan2
- OR5W2 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 58/365 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs924380312, COSV100747744; called by muse, mutect2, varscan2
- PTCHD4 | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 174/430 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749784673; called by muse, mutect2, varscan2
- RALGAPB | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); catalogued as COSV99485309; called by muse, mutect2, varscan2
- SLC43A1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 79/364 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.93); catalogued as rs141938667; called by muse, mutect2, varscan2
- SLCO1A2 | c.589G>T p.G197W | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100261868; called by muse, mutect2
- TAOK1 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.451); catalogued as rs1193577307; called by muse, mutect2, varscan2
- TTN | c.8210G>C p.G2737A (on ENST00000591111; = p.G2691A on NM_003319.4) | Missense Mutation (SNP) | VAF 24/619 reads (4%) | PolyPhen probably damaging (0.999); catalogued as COSV60358869; called by muse, mutect2
- UBN1 | c.3265A>T p.S1089C | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52165966; called by muse, mutect2, varscan2
- VWA8 | c.1782G>A p.W594* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs151124989; called by muse, mutect2, varscan2
- ZWINT | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 72/479 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as rs949337648, COSV59186075; called by muse, mutect2, varscan2
- ADGRV1 | c.8793G>C p.M2931I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANGPTL1 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 115/479 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARC | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CASR | c.2315_2322del p.L772Hfs*129 (on ENST00000490131; = p.L849Hfs*129 on NM_000388.4) | Frame Shift Del (DEL) | VAF 180/1030 reads (17%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.4209_4223del p.T1404_R1408del | In Frame Del (DEL) | VAF 118/408 reads (29%) | called by pindel, varscan2
- CEMIP2 | c.3431G>C p.C1144S | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP91 | c.1635A>T p.Q545H | Missense Mutation (SNP) | VAF 56/439 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- CKM | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 79/454 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CLEC7A | c.459_465del p.N154* (on ENST00000304084 / NM_197947.3; = p.N108* on NM_022570.5) | Frame Shift Del (DEL) | VAF 23/151 reads (15%) | called by mutect2, pindel, varscan2
- CROCC2 | c.4222G>C p.A1408P | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- DEGS2 | c.624del p.V209Wfs*86 | Frame Shift Del (DEL) | VAF 60/305 reads (20%) | called by mutect2, pindel, varscan2
- DNAI4 | c.2426T>A p.V809E | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- DPH5 | c.492C>G p.D164E | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DYNAP | c.87A>T p.R29S (on ENST00000321600; = p.R3S on NM_173629.3) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by muse, mutect2
- ERBB4 | c.2299G>C p.D767H | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FAM187B | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 161/723 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FH | c.538C>G p.H180D | Missense Mutation (SNP) | VAF 93/433 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- FLG | c.12145C>G p.L4049V | Missense Mutation (SNP) | VAF 144/445 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FLT1 | c.2798A>G p.D933G | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GAD2 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR18 | c.322G>C p.A108P | Missense Mutation (SNP) | VAF 102/578 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GPR37 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- GRID2 | c.385A>T p.S129C | Missense Mutation (SNP) | VAF 141/447 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIN2B | c.1315C>G p.R439G | Missense Mutation (SNP) | VAF 100/870 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- H1-10 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HACD2 | c.471A>C p.L157F | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HEATR9 | c.483A>C p.R161S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HIPK2 | c.521A>T p.K174I | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGF1R | c.1888A>C p.K630Q | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2
- IGFALS | c.272C>A p.P91Q | Missense Mutation (SNP) | VAF 109/452 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.216); called by mutect2, varscan2
- ITGAM | c.796T>A p.L266M | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- JAK3 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- KDM5C | c.3617_3627del p.Q1206Pfs*90 | Frame Shift Del (DEL) | VAF 144/400 reads (36%) | called by mutect2, pindel, varscan2
- KIN | c.223_230del p.D75Rfs*10 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- LEMD1 | c.213T>A p.N71K | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LGI4 | c.137T>A p.L46Q | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- LPIN1 | c.1442-3C>G | Splice Region (SNP) | VAF 16/533 reads (3%) | called by muse, mutect2
- MAML3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 127/470 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAP7D1 | c.158C>G p.P53R | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAT1A | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 112/624 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MMRN1 | c.1667A>G p.Q556R | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- MYCBP2 | c.843T>G p.I281M (on ENST00000357337; = p.I319M on NM_015057.5) | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- NAA15 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- NOL9 | c.396G>A p.Q132= | Splice Region (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- NPTX2 | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OLFML2A | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- OTOR | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD3B | c.2047T>G p.Y683D | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.383); called by muse, mutect2
- PGLYRP3 | c.728+2T>C p.X243_splice | Splice Site (SNP) | VAF 62/229 reads (27%) | called by muse, mutect2, varscan2
- PLOD2 | c.1540_1562del p.R514Qfs*6 | Frame Shift Del (DEL) | VAF 30/180 reads (17%) | called by mutect2, pindel, varscan2
- PLPPR1 | c.820T>G p.C274G | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PPP1R14B | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP1R42 | c.687A>T p.K229N | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PRICKLE2 | c.2360G>A p.S787N (on ENST00000295902; = p.S731N on NM_198859.4) | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- PROSER3 | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RBFOX1 | c.815_834del p.L272Rfs*53 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel
- RELN | c.10002G>T p.L3334F | Missense Mutation (SNP) | VAF 71/497 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RELN | c.10001T>A p.L3334* | Nonsense Mutation (SNP) | VAF 72/489 reads (15%) | called by muse, mutect2, varscan2
- RELN | c.8489A>T p.N2830I | Missense Mutation (SNP) | VAF 191/512 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- REM2 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- RSF1 | c.1544G>T p.S515I | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RUSF1 | c.695G>C p.S232T | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RYR2 | c.11499T>G p.D3833E | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC35F3 | c.226G>C p.V76L (on ENST00000366617 / NM_001300845.1; = p.V145L on NM_173508.4) | Missense Mutation (SNP) | VAF 253/1119 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC5A12 | c.230T>G p.F77C | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- STK32B | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, varscan2
- STYX | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SULT1E1 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TACR3 | c.1266G>C p.R422S | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAS1R3 | c.1409A>T p.D470V | Missense Mutation (SNP) | VAF 57/367 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFIP11 | c.364-2A>G p.X122_splice | Splice Site (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- TM9SF4 | c.1111T>C p.S371P | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TP53 | c.574_578del p.Q192Sfs*15 | Frame Shift Del (DEL) | VAF 429/837 reads (51%) | called by mutect2, pindel, varscan2
- TRAF3 | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 136/657 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TRIOBP | c.4349A>T p.Q1450L | Missense Mutation (SNP) | VAF 149/382 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTYH1 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- WDR47 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- WFDC1 | c.144T>A p.R48= | Splice Region (SNP) | VAF 84/269 reads (31%) | called by muse, mutect2, varscan2
- ZNF107 | c.382A>T p.R128* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- ZNF658 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF76 | c.433-32_435del p.X145_splice | Splice Site (DEL) | VAF 109/271 reads (40%) | called by mutect2, pindel, varscan2
- ZYX | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- AC104452.1 | c.585G>C p.L195= | Silent (SNP) | VAF 234/752 reads (31%) | called by muse, mutect2, varscan2
- AK8 | c.1023C>T p.D341= | Silent (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- ALDH1L2 | c.2326C>T p.L776= | Silent (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- ARMC5 | c.2757T>C p.A919= | Silent (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- CAMTA1 | c.3213G>C p.L1071= | Silent (SNP) | VAF 55/271 reads (20%) | called by muse, mutect2, varscan2
- CFAP92 | c.2520C>T p.S840= | Silent (SNP) | VAF 113/774 reads (15%) | called by muse, mutect2, varscan2
- CLEC2B | c.204C>T p.A68= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as rs370109041; called by muse, mutect2, varscan2
- COG8 | c.1302C>T p.P434= | Silent (SNP) | VAF 198/641 reads (31%) | called by muse, mutect2, varscan2
- DNAH8 | c.2236T>C p.L746= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- KANSL2 | c.1314C>G p.V438= | Silent (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- LSS | c.1542G>T p.L514= | Silent (SNP) | VAF 76/521 reads (15%) | called by muse, mutect2, varscan2
- METAP1 | c.1116C>G p.T372= | Silent (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- MIP | c.666T>C p.L222= | Silent (SNP) | VAF 97/508 reads (19%) | catalogued as COSV57516207; called by muse, mutect2, varscan2
- NELFE | c.594A>G p.R198= | Silent (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- NFIC | c.906G>C p.S302= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- NKX3-2 | c.33C>G p.S11= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- OPHN1 | c.2223A>G p.P741= | Silent (SNP) | VAF 96/303 reads (32%) | catalogued as COSV62782664; called by muse, mutect2, varscan2
- PDE2A | c.1029G>T p.V343= | Silent (SNP) | VAF 59/349 reads (17%) | called by muse, mutect2, varscan2
- PEX13 | c.1179C>T p.S393= | Silent (SNP) | VAF 55/240 reads (23%) | called by muse, mutect2, varscan2
- PHLDB1 | c.2262G>A p.L754= | Silent (SNP) | VAF 82/327 reads (25%) | called by muse, mutect2, varscan2
- PTGER4 | c.429C>G p.V143= | Silent (SNP) | VAF 152/896 reads (17%) | called by muse, mutect2, varscan2
- SEC16A | c.4227C>G p.R1409= | Silent (SNP) | VAF 44/173 reads (25%) | called by muse, mutect2, varscan2
- SLC25A4 | c.393C>G p.V131= | Silent (SNP) | VAF 70/317 reads (22%) | called by muse, mutect2, varscan2
- SYNE1 | c.20895G>T p.L6965= (on ENST00000367255 / NM_182961.4; = p.L6894= on NM_033071.3) | Silent (SNP) | VAF 18/534 reads (3%) | called by muse, mutect2
- TSPOAP1 | c.393G>A p.G131= | Silent (SNP) | VAF 12/328 reads (4%) | called by muse, mutect2
- WDR81 | c.1692G>T p.V564= | Silent (SNP) | VAF 122/540 reads (23%) | called by muse, mutect2, varscan2
- ZNF107 | c.381T>C p.T127= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- ZNF438 | c.2235A>T p.G745= | Silent (SNP) | VAF 101/520 reads (19%) | called by muse, mutect2, varscan2
- AL033384.1 | n.258C>A | RNA (SNP) | VAF 49/212 reads (23%) | called by muse, mutect2, varscan2
- CCNQP1 | n.74T>G | RNA (SNP) | VAF 199/602 reads (33%) | called by muse, mutect2, varscan2
- CEP41 | c.*4799G>C | 3'UTR (SNP) | VAF 89/517 reads (17%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812109 A>G | 3'Flank (SNP) | VAF 38/148 reads (26%) | called by muse, mutect2, varscan2
- CREBBP | c.2463+14C>G | Intron (SNP) | VAF 58/178 reads (33%) | called by mutect2, varscan2
- DUOXA1 | chr15:45117687 C>G | 3'Flank (SNP) | VAF 179/291 reads (62%) | called by muse, mutect2, varscan2
- FBLN5 | c.17+451C>G | Intron (SNP) | VAF 70/175 reads (40%) | called by muse, mutect2, varscan2
- IL13RA1 | c.1010-3427C>G | Intron (SNP) | VAF 134/319 reads (42%) | called by muse, mutect2, varscan2
- LRRC27 | chr10:132331530 T>A | 5'Flank (SNP) | VAF 68/261 reads (26%) | called by muse, mutect2, varscan2
- MALRD1 | c.5030-2440C>T | Intron (SNP) | VAF 46/289 reads (16%) | catalogued as rs999550140; called by muse, mutect2
- NSD3 | c.1855+920T>C | Intron (SNP) | VAF 18/87 reads (21%) | catalogued as rs766600639, COSV57617093; called by muse, mutect2, varscan2
- PIPSL | n.541T>C | RNA (SNP) | VAF 125/426 reads (29%) | called by muse, mutect2, varscan2
- TEX36-AS1 | n.514+470A>C | Intron (SNP) | VAF 49/242 reads (20%) | called by muse, mutect2, varscan2
